EXCEPTIONAL_RESPONDERS case ER-AEND — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5953e0ba-9612-4cfd-9f33-0bc114258c94

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1952; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Sigmoid colon; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 55.9 years (20,425 days); Year of diagnosis: 2008; AJCC clinical stage: Stage III; Prior malignancy: no; Days to last follow up: 1,160 days (3.2 years); Days to best overall response: 1,160 days (3.2 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Irinotecan; Days to treatment start: 1,044 days (2.9 years); Days to treatment end: 1,133 days (3.1 years).

Follow-up (1 entry)
- Days to follow up: 1,160 days (3.2 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 48 days; Days progression-free: 1,160 days (3.2 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-AEND-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-AEND-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 20; Percent tumor nuclei: 20; Percent normal cells: 55; Percent necrosis: 5; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
